Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4722, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4722-01A (Primary Tumor).

[page 1 of 3]
Accession #: [REDACTED]
Accession Date: [REDACTED]
Collection Date: [REDACTED]

Attending Physician: M.D. [REDACTED]
Procedure Physician/Copies To: [REDACTED]

Patient Name: [REDACTED]
MRN: [REDACTED]
Location: [REDACTED]

DOB/Age/Sex: [REDACTED]
Account #: [REDACTED]
Patient Type: [REDACTED]
Specimen Class: [REDACTED]
Bench Designate: [REDACTED]

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Laryngeal mass.

PROCEDURE: Biopsy larynx.

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered

PRIOR MALIGNANCY: Not answered

CHEMOTHERAPY: Not answered

ORGAN TRANSPLANT: Not answered

IMMUNOSUPPRESSION: Not answered

OTHER DISEASES: Not answered

FINAL DIAGNOSIS:

PART 1: LARYNX, INTERARYTENOID BIOPSY –

A. KERATOSIS WITH MILD DYSPLASIA.

B. BACTERIA AND YEAST FORMS OF FUNGI CONSISTENT WITH CANDIDA SPECIES.

PART 2: VOCAL PROCESS, LEFT, BIOPSY –

KERATOSIS WITH MILD-TO-MODERATE DYSPLASIA.

PART 3: LARYNX, RIGHT, SUPRAGLOTTIC MASS, BIOPSY –

A. PAPILLARY KERATOSIS WITH MILD DYSPLASIA.

B. YEAST FORMS OF FUNGI CONSISTENT WITH CANDIDA SPECIES.

PART 4: LARYNX, RIGHT, SUPRAGLOTTIC MASS, BIOPSY –

SUPERFICIALLY INVASIVE SQUAMOUS CELL CARCINOMA ARISING IN A BACKGROUND OF PAPILLARY KERATOSIS WITH DYSPLASIA.

PART 5: LARYNX, RIGHT, BIOPSY –

SUPERFICIALLY INVASIVE SQUAMOUS CELL CARCINOMA ARISING IN A BACKGROUND OF PAPILLARY KERATOSIS WITH DYSPLASIA.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

[page 2 of 3]
Pathology Report

GROSS DESCRIPTION:

The specimen is received in five parts:

Part 1 is received in formalin labeled with the patient's name, initials [REDACTED] and "interarytenoid".

Fragment(s): Two, friable

Size(s): 0.2 to 0.3 cm

Cassette(s): 1A.

Part 2 is received in formalin labeled with the patient's name, initials [REDACTED] and "left vocal process biopsy".

Fragment(s): Two

Size(s): 0.1 to 0.3 cm

Cassette(s): 2A.

Part 3 is received in formalin labeled with the patient's name, initials [REDACTED] and "right supraglottic mass".

Fragment(s): Multiple tan-gray, soft and friable fragments

Size(s): 1.3 x 1.3 x 0.3 cm in aggregate

Cassette(s): 3A.

Part 4 is received in formalin labeled with the patient's name, initials [REDACTED] and "right supraglottic mass".

Fragment(s): Four friable

Size(s): 0.3 to 0.5 cm

Cassette(s): 4A.

Part 5 is received in formalin labeled with the patient's name, initials [REDACTED] "right larynx".

Fragment(s): Multiple tan-gray, soft to firm, focally hemorrhagic and cauterized

Size(s): 2.0 x 2.0 x 0.3 cm in aggregate

Cassette(s): 5A, 5B.

DICTATED BY: [REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following immunohistochemical stains were performed and the following results were found:

Stain	Result
Laminin	Highlights mainly basal membranes of blood vessel.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED], as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED].

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

[page 3 of 3]
Pathology Report

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Interarytenoid Biopsy

Taken: [REDACTED]

Stain/cnt Block

HHE x 1 A

H&E x 1 A

Part 2: Left Vocal Process Biopsy

Taken: [REDACTED]

Stain/cnt Block

HHE x 1 A

H&E x 1 A

Part 3: Right Supraglottic Mass

Taken: [REDACTED]

Stain/cnt Block

HHE x 1 A

H&E x 1 A

Part 4: Right Subglottic Mass

Taken: [REDACTED]

Stain/cnt Block

ANEG x 1 A

RHHE Lev ____ x 3 A

HHE x 1 A

H&E x 1 A

LaminIn RED x 1 A

Part 5: Right Larynx

Taken: [REDACTED]

Stain/cnt Block

RHHE Lev ____ x 3 A

HHE x 1 A

H&E x 1 A

RHHE Lev ____ x 3 B

HHE x 1 B

H&E x 1 B

ICD-9 Diagnosis Codes: {None Entered}

Source: NCI Genomic Data Commons file 093ad167-702d-4ab6-9af9-952dbe2715fb (TCGA-CN-4722.52B0E2FC-E8BB-4BC3-B343-F8A1692B5DC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).